FM case AD9447 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Rectum.
https://portal.gdc.cancer.gov/cases/1c1904b0-3c88-479c-9780-38c58d19b481

Female, 73.4 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the rectum; metastasis biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
